Somatic mutation profile of tumor specimen TCGA-DS-A1OB-01A (aliquot TCGA-DS-A1OB-01A-11D-A16Y-08) from TCGA case TCGA-DS-A1OB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 45.7 years (16,685 days).
Specimen TCGA-DS-A1OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c0be747-8af1-444e-be75-610d0007483d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A1OB-10A (Blood Derived Normal), aliquot TCGA-DS-A1OB-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1465316-3c72-4cc2-8d0a-4aa696a9b697

The open-access MAF lists 618 somatic variants for this specimen: 421 protein-altering or splice-affecting, 187 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 369, Silent 187, Nonsense Mutation 37, Intron 6, Frame Shift Del 5, Splice Site 4, Splice Region 3, RNA 2, Nonstop Mutation 1, In Frame Del 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 56/203 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXL2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs387906920, CM035545, COSV57729356; ClinVar: pathogenic; called by mutect2, varscan2
- OPHN1 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs1057520737, COSV100830535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 25/29 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/21 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC22A12 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs121907893, CM023584, COSV60571649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV101330086, COSV70031688; called by muse, mutect2, varscan2
- ABCA9 | c.4360G>A p.E1454K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs774507778, COSV60631810; called by muse, mutect2, varscan2
- ABCB4 | c.3046C>G p.L1016V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55933558, COSV99710622; called by muse, mutect2, varscan2
- ABCB5 | c.3325G>A p.E1109K (on ENST00000404938 / NM_001163941.2; = p.E664K on NM_178559.6) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs377436901, COSV51715362; called by muse, mutect2, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- ABCF1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.912); catalogued as rs150508727, COSV100400964; called by muse, mutect2, varscan2
- ABHD8 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs138969474; called by muse, mutect2, varscan2
- AC008397.2 | c.1706T>C p.F569S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441817; called by muse, mutect2, varscan2
- ACHE | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99574219; called by muse, mutect2, varscan2
- ACOX3 | c.1906G>T p.D636Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100711969, COSV62711408; called by muse, mutect2, varscan2
- ACSBG2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV99397476; called by muse, mutect2, varscan2
- ADAMTS15 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.335); catalogued as COSV54503824; called by muse, mutect2, varscan2
- ADCY3 | c.3020G>C p.R1007T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53172130; called by muse, mutect2, varscan2
- AFDN | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV100652951, COSV100653101; called by muse, mutect2, varscan2
- AFF3 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as COSV100419214; called by muse, mutect2, varscan2
- AIM2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs145779112; called by mutect2, varscan2
- AKAP4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs782072348, COSV100654286; called by muse, mutect2, varscan2
- AKAP6 | c.3403C>T p.R1135* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as COSV55209080; called by muse, mutect2
- AKIRIN1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100881984; called by muse, mutect2, varscan2
- AKR1A1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs767717870, COSV100698745; called by muse, mutect2, varscan2
- AKR1A1 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as rs755890684, COSV61087000; called by mutect2, varscan2
- ALPK3 | c.2660C>A p.P887Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV99361149; called by muse, mutect2, varscan2
- ANGPTL7 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100816289, COSV63879290; called by muse, mutect2, varscan2
- ARHGAP39 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV99431544; called by muse, mutect2, varscan2
- ARHGEF19 | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.611); catalogued as COSV99580537; called by muse, mutect2, varscan2
- ARID4B | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.525); catalogued as COSV99935763; called by muse, mutect2, varscan2
- ARL2BP | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs1057111225, COSV99536094; called by muse, mutect2, varscan2
- ARSF | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV63840369; called by muse, mutect2, varscan2
- ASPRV1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs780283982, COSV57228772; called by muse, mutect2, varscan2
- ASXL2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV99711356; called by muse, mutect2
- ATE1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56436873, COSV99817292; called by muse, mutect2, varscan2
- ATP6V0A1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV99231146; called by muse, mutect2, varscan2
- AXL | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99996696; called by muse, mutect2, varscan2
- B3GLCT | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541884125, COSV58456973; called by mutect2, varscan2
- B4GALNT3 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747342036, COSV99843140; called by muse, mutect2, varscan2
- BICDL1 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57492946; called by muse, mutect2, varscan2
- BRD4 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV54592638, COSV99650879; called by muse, varscan2
- BRD7 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV101164987, COSV101165042; called by muse, mutect2, varscan2
- C14orf119 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as COSV99399783; called by muse, mutect2, varscan2
- C9orf24 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as rs1449417201, COSV99897987; called by muse, mutect2, varscan2
- CAND1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV101598279; called by muse, mutect2, varscan2
- CARF | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.036); catalogued as COSV100247702; called by muse, varscan2
- CARMIL1 | c.4075G>A p.D1359N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100278109; called by muse, mutect2, varscan2
- CASP8AP2 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99387127; called by muse, mutect2, varscan2
- CCAR1 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56275100; called by muse, varscan2
- CCAR1 | c.1008G>T p.R336S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99771105; called by muse, varscan2
- CCDC141 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV99836944; called by muse, varscan2
- CCDC40 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as rs773268055, COSV99481857; called by muse, mutect2, varscan2
- CDC6 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV99266608; called by muse, varscan2
- CDH22 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV64836903; called by muse, mutect2, varscan2
- CDHR5 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV100848577; called by muse, varscan2
- CDK12 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV101420481; called by muse, mutect2, varscan2
- CEP128 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825005; called by muse, mutect2, varscan2
- CEP152 | c.5107G>C p.D1703H (on ENST00000380950 / NM_001194998.2; = p.D1647H on NM_014985.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100358889; called by muse, mutect2, varscan2
- CEP72 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99374921; called by muse, mutect2, varscan2
- CFAP46 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99585004; called by muse, mutect2, varscan2
- CHAT | c.1888C>A p.L630M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV100340279; called by muse, mutect2, varscan2
- CHD1L | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100787488; called by muse, mutect2, varscan2
- CHRNB1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548353; called by muse, varscan2
- CHRNB1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs146117123, COSV99548358; called by muse, varscan2
- CHST1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1564995555, COSV57325381; called by muse, mutect2, varscan2
- CLCN5 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs782817681, CM165162, COSV100259860; ClinVar: benign; called by muse, mutect2, varscan2
- CLMN | c.2177T>C p.L726P | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs993458899, COSV54178927, COSV54180366; called by muse, varscan2
- CLMN | c.2066G>A p.S689N | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460560076, COSV54179513; called by muse, varscan2
- CLP1 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100239839; called by muse, mutect2, varscan2
- CLPTM1 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100493806; called by muse, mutect2, varscan2
- CLVS2 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV99252964; called by muse, mutect2
- CNOT3 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99651999; called by muse, mutect2, varscan2
- CNST | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV100829873; called by muse, mutect2, varscan2
- COBLL1 | c.2005C>T p.Q669* (on ENST00000392717; = p.Q631* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as COSV52071856, COSV99528123; called by muse, mutect2, varscan2
- COL1A1 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760860681, COSV56805466; called by muse, mutect2, varscan2
- COL22A1 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.187); catalogued as COSV57360298; called by muse, mutect2
- COL27A1 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100621049; called by muse, mutect2, varscan2
- COL4A4 | c.4880G>C p.R1627T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100307031, COSV61633330; called by muse, mutect2, varscan2
- CORO2A | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.866); catalogued as COSV100674038; called by muse, mutect2, varscan2
- CPLANE1 | c.7916C>T p.S2639L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs79399627, COSV99950823; called by mutect2, varscan2
- CPNE6 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV53742753, COSV99393510; called by muse, mutect2, varscan2
- CREBBP | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99270483; called by muse, mutect2, varscan2
- CRX | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV99704547; called by muse, mutect2, varscan2
- CUL7 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779355111, COSV99538768; called by muse, mutect2, varscan2
- DAGLA | c.408C>T p.L136= | Splice Region (SNP) | VAF 18/44 reads (41%) | catalogued as rs747365475, COSV57194616, COSV57200656; called by muse, mutect2
- DBF4 | c.810-1G>A p.X270_splice | Splice Site (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99719375; called by muse, mutect2, varscan2
- DCBLD1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs138390701; called by muse, varscan2
- DDX18 | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54308766; called by muse, mutect2, varscan2
- DDX23 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56400955, COSV99974937; called by muse, mutect2, varscan2
- DDX3X | c.759G>A p.M253I (on ENST00000399959; = p.M254I on NM_001356.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV67864516; called by muse, mutect2, varscan2
- DEGS2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99979237; called by muse, mutect2, varscan2
- DENND5A | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100064817; called by muse, mutect2, varscan2
- DGAT2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.969); catalogued as COSV99929820; called by muse, mutect2, varscan2
- DGKK | c.2004G>A p.M668I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101053057, COSV65706364; called by muse, mutect2, varscan2
- DHX16 | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770541590, COSV99528021; called by muse, mutect2, varscan2
- DHX32 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs377344904; called by muse, varscan2
- DHX32 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99501727; called by muse, varscan2
- DMD | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as CM910110, COSV100820224, COSV63790473; called by muse, mutect2, varscan2
- DNAH10 | c.6331C>T p.P2111S (on ENST00000409039; = p.P2050S on NM_207437.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101292329; called by muse, mutect2, varscan2
- DNAH3 | c.9286G>A p.E3096K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54550870; called by muse, mutect2, varscan2
- DNAH3 | c.3995G>T p.G1332V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.758); catalogued as COSV54554224, COSV99768100; called by muse, varscan2
- DNAH8 | c.11816C>T p.S3939L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545830, COSV59464761; called by mutect2, varscan2
- DNAH9 | c.5044C>T p.H1682Y | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs1292046143, COSV99306304; called by muse, mutect2, varscan2
- DNAJB12 | c.362G>A p.G121E (on ENST00000338820; = p.G87E on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.691); catalogued as COSV100123826; called by muse, mutect2, varscan2
- DNAJB14 | c.1083G>C p.L361F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100508520; called by muse, varscan2
- DNAJC24 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV101519667; called by muse, mutect2, varscan2
- DNTTIP1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV99708539, COSV99708638; called by muse, mutect2, varscan2
- DOCK4 | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV101312830, COSV69854077; called by muse, mutect2, varscan2
- DOT1L | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV101288696; called by muse, mutect2, varscan2
- DOT1L | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs947488803, COSV101288699; called by muse, mutect2, varscan2
- DOT1L | c.3023C>G p.S1008C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); catalogued as rs778747333, COSV101288700; called by muse, mutect2, varscan2
- DSG1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99936126; called by muse, mutect2, varscan2
- DSG3 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57125755, COSV99934306; called by muse, mutect2, varscan2
- DSP | c.4677C>A p.F1559L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101131359; called by muse, mutect2, varscan2
- DSP | c.6605C>G p.S2202* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101131360, COSV65792182; called by muse, mutect2, varscan2
- DUSP21 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100173594; called by muse, mutect2, varscan2
- EDEM2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100993783; called by muse, mutect2, varscan2
- EDEM3 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.189); catalogued as COSV100545401, COSV100545653; called by muse, mutect2, varscan2
- EHD1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100277081; called by muse, mutect2, varscan2
- EIF2AK1 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.759); catalogued as rs1007954194, COSV99552021; called by muse, mutect2
- ELOA | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs377449904; called by muse, mutect2, varscan2
- EMB | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57483161; called by muse, mutect2, varscan2
- EP300 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX162052; called by muse, mutect2, varscan2
- ERO1A | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101193638; called by muse, mutect2, varscan2
- ETFDH | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV56987760; called by muse, mutect2, varscan2
- EVC2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV100186169; called by muse, mutect2, varscan2
- EVI5L | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99563244; called by muse, mutect2, varscan2
- EXOC3L1 | c.1581G>C p.R527S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99333768; called by muse, mutect2, varscan2
- EXOSC5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs754247072, COSV55370676, COSV55372173; called by muse, mutect2, varscan2
- FAAP20 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs561468605, COSV101052021; called by muse, mutect2, varscan2
- FAM114A2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV100491648; called by muse, mutect2
- FAM193A | c.3427G>C p.E1143Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100219037, COSV100219291; called by muse, mutect2, varscan2
- FAM71B | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV100262152; called by muse, mutect2, varscan2
- FAT2 | c.7147C>T p.Q2383* | Nonsense Mutation (SNP) | VAF 40/53 reads (75%) | catalogued as COSV55821719, COSV99943211; called by muse, mutect2, varscan2
- FAT2 | c.5581C>T p.H1861Y | Missense Mutation (SNP) | VAF 94/112 reads (84%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99943226, COSV99944532; called by muse, varscan2
- FBLIM1 | c.1121G>C p.*374Sext*33 | Nonstop Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as COSV100181773; called by muse, mutect2, varscan2
- FCRL4 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs371253687; called by muse, mutect2, varscan2
- FGF11 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.476); catalogued as rs756454648, COSV53439679; called by muse, mutect2, varscan2
- FHDC1 | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99471376; called by muse, mutect2, varscan2
- FHDC1 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs748687461, COSV99471379; called by mutect2, varscan2
- FKBP10 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.02); catalogued as COSV54055716, COSV99505225; called by muse, mutect2, varscan2
- FLNA | c.2642G>C p.G881A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100774810; called by muse, mutect2, varscan2
- FMNL1 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100056596, COSV100057143, COSV58958238; called by muse, mutect2, varscan2
- FOXD2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100599259; called by muse, varscan2
- GAB4 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101272005; called by muse, varscan2
- GABRD | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV66079847; called by muse, mutect2, varscan2
- GANAB | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100647994; called by muse, mutect2, varscan2
- GCN1 | c.5874G>C p.E1958D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV100325455, COSV56113837; called by muse, mutect2, varscan2
- GMNN | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV100017742; called by muse, mutect2, varscan2
- GNAI3 | c.910C>G p.Q304E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV100879903, COSV63983248; called by muse, mutect2, varscan2
- GOLGA1 | c.1917G>C p.Q639H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99414562; called by muse, mutect2, varscan2
- GOLGB1 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.447); catalogued as COSV100511595, COSV61465606; called by muse, mutect2, varscan2
- GPATCH2 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as COSV100861393, COSV65127551; called by muse, mutect2, varscan2
- GPC4 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100895505; called by muse, mutect2, varscan2
- GRIK2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.457); catalogued as COSV59714181; called by muse, mutect2, varscan2
- GRIN2D | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99616563; called by muse, varscan2
- GRM4 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1373099968, COSV100946318; called by muse, mutect2
- GSTK1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 108/129 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100621803; called by muse, varscan2
- GTF2I | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100259668; called by muse, mutect2, varscan2
- HBB | c.318C>A p.L106= | Splice Region (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100092796, COSV58942786, COSV58943352; called by muse, mutect2, varscan2
- HIRA | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99600490; called by mutect2, varscan2
- HOATZ | c.418C>T p.P140S (on ENST00000375618 / NM_001100388.1; = p.P167S on NM_207430.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV60441617; called by muse, varscan2
- HOMER2 | c.1057G>A p.D353N (on ENST00000304231 / NM_199330.3; = p.D342N on NM_004839.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs1243577936, COSV100420398; called by muse, mutect2, varscan2
- HSPBAP1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60241851; called by mutect2, varscan2
- HSPG2 | c.12808G>C p.V4270L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV100760815; called by muse, mutect2, varscan2
- HUWE1 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99472767; called by muse, mutect2, varscan2
- IBSP | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99883614; called by muse, mutect2, varscan2
- IL17RA | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100083203, COSV100083399; called by muse, mutect2, varscan2
- IL2RA | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906741; called by muse, mutect2, varscan2
- ILDR2 | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99613992; called by muse, mutect2
- ILDR2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV54829134; called by muse, mutect2, varscan2
- INPP5B | c.1723G>A p.E575K (on ENST00000373023; = p.E495K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV100886521; called by muse, varscan2
- IPO4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs760564068, COSV99938103; called by muse, mutect2, varscan2
- IQCA1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV54498847, COSV99609713; called by muse, mutect2, varscan2
- IRF1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777589347, COSV99810566; called by muse, mutect2, varscan2
- IRGQ | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV100338176; called by muse, mutect2, varscan2
- ITGBL1 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs753390115, COSV66006406; called by muse, mutect2, varscan2
- ITSN2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs745556945, COSV100743678, COSV61945037; called by muse, mutect2
- KCNA4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); catalogued as COSV100069035; called by muse, mutect2, varscan2
- KCNJ4 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs111561943, COSV57858874; called by muse, mutect2, varscan2
- KCNT2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99654422; called by muse, mutect2, varscan2
- KDELR2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs771624924, COSV99330620, COSV99330709; called by muse, varscan2
- KDM3A | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979151200, COSV100459951; called by muse, mutect2, varscan2
- KLC4 | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as COSV99432092; called by muse, mutect2, varscan2
- KLRC2 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV101122707; called by muse, mutect2, varscan2
- KMT2C | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 67/87 reads (77%) | catalogued as COSV51440123; called by muse, mutect2, varscan2
- KMT2D | c.10321C>T p.Q3441* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV56427390; called by muse, mutect2, varscan2
- KRT36 | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100057591; called by muse, mutect2, varscan2
- KRTAP10-1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782124753, COSV59956003; called by mutect2, varscan2
- KTI12 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as COSV100860207, COSV65405615; called by muse, mutect2, varscan2
- LAMA2 | c.5680G>C p.E1894Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101370548; called by muse, mutect2, varscan2
- LAMB2 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs779353027, COSV100565281; called by muse, mutect2, varscan2
- LAMB2 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 62/86 reads (72%) | catalogued as COSV100565284; called by muse, mutect2, varscan2
- LCA5 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100878301; called by muse, mutect2, varscan2
- LGALS12 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs751524117, COSV55371326, COSV99737404; called by muse, mutect2, varscan2
- LHX6 | c.838C>T p.Q280* (on ENST00000373755 / NM_001242334.2; = p.Q309* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100493462; called by muse, mutect2
- LIG1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99619027; called by muse, varscan2
- LIX1 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 37/49 reads (76%) | catalogued as COSV99172929; called by muse, mutect2, varscan2
- LMO7 | c.2713C>G p.Q905E (on ENST00000357063; = p.Q586E on NM_005358.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100413387; called by mutect2, varscan2
- LMOD2 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV101505449; called by muse, mutect2, varscan2
- LRFN4 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100540809; called by muse, mutect2, varscan2
- LUM | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99899070; called by muse, varscan2
- LYG2 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs1272979120, COSV100283489; called by muse, mutect2, varscan2
- MAF1 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100075634; called by muse, mutect2, varscan2
- MAMLD1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99476117; called by muse, mutect2
- MAP3K1 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV68123021; called by muse, varscan2
- MAP3K11 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV100482564; called by muse, mutect2, varscan2
- MAP3K6 | c.3766G>A p.D1256N | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100539388; called by muse, mutect2, varscan2
- MAP3K6 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 49/169 reads (29%) | catalogued as COSV99585378; called by muse, mutect2, varscan2
- MDC1 | c.4783C>T p.R1595W | Missense Mutation (SNP) | VAF 95/569 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs762832250, COSV64524320; called by muse, mutect2, varscan2
- MFSD13A | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | catalogued as COSV53267338, COSV99487920; called by muse, mutect2, varscan2
- MGAM | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV71885936; called by muse, mutect2, varscan2
- MGAT5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV99924604; called by muse, mutect2, varscan2
- MGAT5 | c.2215G>C p.D739H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56096505, COSV99924605; called by muse, mutect2, varscan2
- MGME1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757861031, COSV100891359; called by muse, mutect2, varscan2
- MOCS3 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99724303; called by muse, varscan2
- MON1B | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.883); catalogued as COSV50247497; called by muse, mutect2, varscan2
- MOSPD3 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99774969; called by muse, varscan2
- MOSPD3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs757636025, COSV99774970; called by muse, varscan2
- MPP5 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV99907143; called by muse, mutect2, varscan2
- MPV17 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as COSV99274399; called by muse, mutect2, varscan2
- MR1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368060940, COSV51580280; called by muse, mutect2, varscan2
- MRPS31 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100062279; called by muse, mutect2, varscan2
- MRPS5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99720865; called by muse, mutect2, varscan2
- MSR1 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1314718336, COSV100027457, COSV50531562; called by muse, mutect2, varscan2
- MTURN | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.361); catalogued as COSV100188818; called by muse, mutect2
- MUC17 | c.12139C>T p.P4047S | Missense Mutation (SNP) | VAF 88/497 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100073763; called by muse, mutect2, varscan2
- MUC5B | c.11213C>T p.T3738M | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs370745091; called by muse, mutect2, varscan2
- MX2 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV58099245; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- MYH7 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100806216; called by muse, mutect2, varscan2
- MYORG | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); catalogued as COSV52627121, COSV99898671; called by muse, varscan2
- NAP1L4 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV101000714; called by muse, mutect2, varscan2
- NAV1 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV55227180; called by muse, mutect2, varscan2
- NBR1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57835472; called by muse, varscan2
- NBR1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100357882, COSV57830568; called by muse, varscan2
- NCKAP1L | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs779095429, COSV53207224; called by muse, mutect2, varscan2
- NCKAP5 | c.4766G>A p.R1589K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100492598; called by muse, mutect2, varscan2
- NDNF | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV101113189; called by muse, mutect2, varscan2
- NDUFS1 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV99261058; called by muse, mutect2, varscan2
- NEMF | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs764224132, COSV53590766; called by mutect2, varscan2
- NEU4 | c.506C>T p.S169L (on ENST00000391969 / NM_001167602.3; = p.S181L on NM_080741.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100372069; called by muse, mutect2, varscan2
- NLRP5 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774293395, COSV66767639; called by muse, mutect2, varscan2
- NOP14 | c.2238G>C p.Q746H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs770027682, COSV100054715; called by muse, mutect2, varscan2
- NOXO1 | c.394G>C p.E132Q (on ENST00000397280 / NM_172168.3; = p.E126Q on NM_144603.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1323699663, COSV99937054; called by muse, mutect2, varscan2
- NPAT | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99586106; called by muse, mutect2, varscan2
- NPC1L1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.291); catalogued as COSV99212345; called by muse, mutect2, varscan2
- NSD3 | c.2091G>C p.M697I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100388711; called by muse, mutect2, varscan2
- NUFIP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 279/1013 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56603507; called by muse, mutect2, varscan2
- NWD1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV100342883; called by muse, mutect2, varscan2
- NXF3 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 108/373 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV101221990; called by muse, mutect2, varscan2
- NYAP1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs758261267, COSV100278531; called by muse, mutect2, varscan2
- NYAP2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV99797058; called by muse, mutect2, varscan2
- OBSCN | c.14095C>G p.Q4699E | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV99479960; called by muse, mutect2, varscan2
- OBSL1 | c.2804G>C p.G935A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99216975; called by muse, mutect2, varscan2
- OIT3 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.721); catalogued as COSV100468061, COSV61826820; called by muse, mutect2, varscan2
- OR1M1 | c.791C>G p.S264W | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101447568, COSV101447600; called by muse, mutect2, varscan2
- OR4N5 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61321454; called by muse, mutect2, varscan2
- PC | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV100547113; called by muse, varscan2
- PC | c.2417C>G p.S806* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100547114; called by muse, varscan2
- PC | c.2090G>C p.G697A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100547115; called by muse, mutect2, varscan2
- PCDH10 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99993773; called by muse, mutect2, varscan2
- PCDH17 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220400732, COSV100931573; called by muse, varscan2
- PCDHA4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV100793545; called by muse, mutect2, varscan2
- PCDHA6 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65342026; called by muse, varscan2
- PCDHB11 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 70/98 reads (71%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.092); catalogued as COSV100697035; called by muse, mutect2, varscan2
- PCDHB7 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV50768803, COSV99177060; called by muse, mutect2, varscan2
- PCDHGA10 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99540060; called by muse, varscan2
- PCDHGA10 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53900893; called by muse, mutect2, varscan2
- PCSK4 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs200520395; called by muse, varscan2
- PDCD2L | c.214C>G p.H72D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs775637690, COSV99874855, COSV99875020; called by muse, mutect2, varscan2
- PEAK1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100433110; called by muse, mutect2, varscan2
- PFKFB4 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 67/93 reads (72%) | PolyPhen benign (0.109); catalogued as COSV99219714; called by muse, mutect2, varscan2
- PHLDB2 | c.2717C>T p.S906F (on ENST00000393925 / NM_001134439.2; = p.S863F on NM_145753.2) | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101208562, COSV67309361; called by muse, mutect2, varscan2
- PIK3CA | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV55988096, COSV99838734; called by muse, mutect2, varscan2
- PIKFYVE | c.4427C>G p.S1476C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100010889; called by muse, mutect2, varscan2
- PLAA | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101263528; called by muse, mutect2, varscan2
- PLAGL1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as rs1221932465, COSV99394476; called by muse, mutect2, varscan2
- PLCD1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378956; called by muse, mutect2, varscan2
- PLD6 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.003); catalogued as rs756356336, COSV100387554; called by muse, mutect2, varscan2
- PLPP1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs757205685; called by muse, mutect2, varscan2
- PLXDC2 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101023016; called by muse, mutect2, varscan2
- PMF1 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100196204; called by muse, mutect2, varscan2
- PMS1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575681; called by muse, mutect2, varscan2
- PNMA1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV99678955; called by muse, mutect2, varscan2
- PNMA1 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1555341234, COSV99678956; called by muse, varscan2
- PNMA1 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1191983235, COSV99678960; called by muse, varscan2
- POLE | c.3538C>T p.Q1180* | Nonsense Mutation (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100267099; called by muse, mutect2, varscan2
- PPP1R12A | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99700454; called by muse, mutect2, varscan2
- PREX2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs777080876, COSV55774169, COSV55804768; called by muse, mutect2, varscan2
- PRICKLE1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs765119777, COSV61546909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCI | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99855935; called by muse, mutect2, varscan2
- PROP1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs570907973, COSV57644723; called by muse, mutect2, varscan2
- PSG8 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1239842104, COSV100126318, COSV60610870; called by muse, mutect2, varscan2
- PTMA | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV100398408; called by muse, mutect2, varscan2
- PTPRF | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.734); catalogued as COSV100740982; called by muse, mutect2, varscan2
- RAPGEF4 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99910812; called by muse, mutect2, varscan2
- RASAL2 | c.2777G>C p.R926T | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV100862682, COSV62713871; called by muse, mutect2, varscan2
- RASD1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99245823; called by muse, varscan2
- RASEF | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756597281, COSV100906930; called by muse, mutect2, varscan2
- RASGRF2 | c.2962C>G p.Q988E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1177941622, COSV99429509; called by muse, mutect2, varscan2
- RASSF8 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV51454676; called by muse, mutect2, varscan2
- RHOA | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV69042644; called by muse, varscan2
- RHOBTB1 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450912393, COSV61959466; called by muse, mutect2, varscan2
- RNF149 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV99766627; called by muse, varscan2
- RSL1D1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.077); catalogued as rs1400149329, COSV100851992, COSV63077476; called by muse, mutect2, varscan2
- RSPH10B | c.1470G>C p.L490F | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.989); catalogued as COSV100521327; called by muse, mutect2, varscan2
- RTEL1 | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100542465; called by muse, mutect2, varscan2
- RUNX1 | c.218C>T p.S73F (on ENST00000344691 / NM_001001890.3; = p.S100F on NM_001754.5) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55868630, COSV55869047; called by muse, mutect2, varscan2
- RYR1 | c.5480G>A p.R1827H | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769949286, COSV62100868; called by muse, mutect2, varscan2
- RYR3 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV66793885; called by muse, varscan2
- SAMD15 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as rs777138168, COSV99375029; called by muse, mutect2, varscan2
- SAMD3 | c.682C>G p.R228G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100931800, COSV63712931; called by muse, varscan2
- SAMD9 | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV66074298, COSV66077262; called by muse, mutect2, varscan2
- SARM1 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50229704, COSV99135004; called by muse, mutect2, varscan2
- SENP5 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs766110657, COSV60207241, COSV60207810; called by muse, mutect2, varscan2
- SHC4 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV60111912; called by muse, mutect2, varscan2
- SLC12A5 | c.1298C>T p.S433L (on ENST00000454036 / NM_001134771.2; = p.S410L on NM_020708.5) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV54795298; called by muse, mutect2, varscan2
- SLC25A10 | c.375C>T p.V125= | Splice Region (SNP) | VAF 57/135 reads (42%) | catalogued as COSV100519060; called by muse, mutect2, varscan2
- SLC26A6 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | catalogued as COSV99373796; called by muse, mutect2, varscan2
- SLC26A8 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100839505; called by muse, mutect2, varscan2
- SLFN12 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100513116, COSV59227102; called by muse, mutect2, varscan2
- SLFNL1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs376892209, COSV57235116; called by muse, mutect2, varscan2
- SLIT3 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs774734291, COSV100265764, COSV100268135; called by muse, mutect2, varscan2
- SLITRK5 | c.2667C>G p.F889L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs777163946, COSV100280868; called by muse, mutect2, varscan2
- SLX4 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV99568137; called by muse, mutect2, varscan2
- SMC4 | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100644061; called by muse, mutect2, varscan2
- SMG9 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.186); catalogued as rs200906288, COSV99526769; called by muse, mutect2
- SMYD3 | c.353C>T p.S118L (on ENST00000490107 / NM_001375962.1; = p.S59L on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as COSV101194090; called by muse, mutect2, varscan2
- SNX15 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as COSV100101146; called by muse, mutect2, varscan2
- SNX9 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV101094041; called by muse, varscan2
- SP1 | c.2009C>T p.S670L (on ENST00000327443 / NM_138473.3; = p.S663L on NM_003109.1) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1452658388, COSV100540696; called by muse, mutect2, varscan2
- SPACA3 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs761508766, COSV99284211; called by muse, mutect2, varscan2
- SPDYC | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV101017232; called by muse, mutect2, varscan2
- SPEG | c.9012G>C p.K3004N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100404759; called by muse, mutect2, varscan2
- SPIC | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746088939, COSV54690815; called by muse, mutect2, varscan2
- SPRR1B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1223340826, COSV100198372; called by muse, mutect2, varscan2
- SPZ1 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.821); catalogued as COSV99698306; called by muse, mutect2
- SREBF1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99889024; called by muse, mutect2, varscan2
- SRP72 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100714319, COSV61377488; called by muse, varscan2
- SRSF3 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100244861; called by muse, mutect2, varscan2
- SSTR1 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV57457372; called by muse, mutect2, varscan2
- SUCLG1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101205428; called by muse, mutect2, varscan2
- SYNE1 | c.11950C>G p.Q3984E (on ENST00000367255 / NM_182961.4; = p.Q3913E on NM_033071.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99567622; called by muse, mutect2, varscan2
- SYTL1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV100539384; called by muse, mutect2, varscan2
- SZT2 | c.9760G>A p.E3254K (on ENST00000634258 / NM_001365999.1; = p.E3197K on NM_015284.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1221822304, COSV100981298; called by muse, varscan2
- TAC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100071141; called by muse, mutect2, varscan2
- TACC2 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100552583, COSV57759531; called by muse, mutect2, varscan2
- TAF1L | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141239475; called by muse, varscan2
- TARS2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs367984492, COSV100946011; called by muse, mutect2, varscan2
- TBCD | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100833393; called by muse, mutect2, varscan2
- TBL2 | c.262-1G>C p.X88_splice | Splice Site (SNP) | VAF 46/128 reads (36%) | catalogued as COSV99979648; called by muse, varscan2
- TBX20 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs13237089, COSV101282388; called by muse, mutect2, varscan2
- TCF21 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as rs1243221906, COSV52818803; called by muse, mutect2, varscan2
- TCTE3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs138550412; called by muse, mutect2, varscan2
- TECTB | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV101027713; called by muse, mutect2, varscan2
- TENM3 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as COSV101305182; called by muse, mutect2, varscan2
- TFPI2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as rs770380317, COSV55990401, COSV55992087; called by muse, mutect2, varscan2
- THOC5 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV100803611; called by mutect2, varscan2
- THOP1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100310621; called by muse, mutect2, varscan2
- TM7SF2 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54208746, COSV99659687; called by muse, mutect2, varscan2
- TMCC2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs752001776, COSV58004319; called by muse, mutect2, varscan2
- TMCO2 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.839); catalogued as rs764404915, COSV101033773; called by muse, mutect2, varscan2
- TMEM51 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as rs201213892, COSV65691240; called by muse, mutect2, varscan2
- TNXB | c.5344G>A p.E1782K (on ENST00000647633; = p.E1535K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV100926402, COSV64487647; called by muse, mutect2, varscan2
- TOP1 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV100793859, COSV100794051, COSV63693020; called by muse, varscan2
- TP53BP1 | c.5482C>T p.H1828Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780546857, COSV99539133; called by muse, mutect2, varscan2
- TPI1 | c.479G>A p.G160E (on ENST00000229270; = p.G123E on NM_000365.6) | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV99222918; called by muse, mutect2, varscan2
- TPRN | c.1242G>C p.Q414H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100285871; called by muse, varscan2
- TRIM48 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.508); catalogued as rs1356619563, COSV70161826; called by muse, mutect2, varscan2
- UBE2J2 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs146718362; called by muse, mutect2, varscan2
- UPF1 | c.3055C>T p.R1019* (on ENST00000599848 / NM_001297549.2; = p.R1008* on NM_002911.4) | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV53193464; called by muse, mutect2, varscan2
- UQCC1 | c.766-1G>C p.X256_splice | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100568632; called by muse, varscan2
- UQCRC2 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99193341; called by muse, mutect2, varscan2
- USH2A | c.3527C>T p.S1176F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100236705, COSV56389994; called by muse, mutect2, varscan2
- USP3 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99165727; called by muse, mutect2, varscan2
- VRK1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99388478; called by muse, mutect2, varscan2
- VRK1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99388480; called by muse, mutect2
- WASHC2C | c.1833G>C p.K611N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV60493880; called by muse, mutect2, varscan2
- WDPCP | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99705615; called by muse, mutect2, varscan2
- WDR26 | c.2047G>A p.E683K (on ENST00000414423 / NM_001379403.1; = p.E583K on NM_025160.7) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99691297; called by muse, mutect2, varscan2
- WNK3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100671556, COSV63615443; called by muse, mutect2, varscan2
- WSB2 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as COSV99969916; called by muse, mutect2, varscan2
- XPNPEP1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776040608, COSV100450957; called by muse, varscan2
- YRDC | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100888649; called by muse, mutect2, varscan2
- YWHAZ | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV62053827; called by muse, mutect2, varscan2
- ZC3H7A | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV63269656, COSV63271771; called by muse, varscan2
- ZNF100 | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59746449, COSV99974095; called by muse, mutect2, varscan2
- ZNF100 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1568288371, COSV99974099; called by muse, varscan2
- ZNF208 | c.3114C>A p.F1038L | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV101237055, COSV68112389; called by muse, mutect2, varscan2
- ZNF226 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV100335174; called by muse, mutect2, varscan2
- ZNF311 | c.1871C>G p.S624* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs750403592, COSV101014156; called by muse, mutect2, varscan2
- ZNF311 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101014157; called by muse, mutect2, varscan2
- ZNF324B | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100351686; called by muse, varscan2
- ZNF331 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99467465; called by muse, mutect2, varscan2
- ZNF492 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV101514009; called by muse, mutect2, varscan2
- ZNF582 | c.365G>C p.W122S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100018758; called by muse, mutect2, varscan2
- ZNF613 | c.790G>A p.E264K (on ENST00000293471 / NM_001031721.4; = p.E228K on NM_024840.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV99522958; called by muse, varscan2
- ZNF777 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as COSV99925219; called by muse, mutect2, varscan2
- AKAP6 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- CNOT6L | c.1443_1452del p.F482Kfs*3 (on ENST00000504123 / NM_001286790.2; = p.F477Kfs*3 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- H3-3A | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5B | c.1783G>C p.E595Q (on ENST00000373023; = p.E515Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IPO9 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- KIAA1109 | c.5416C>T p.L1806F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- LARP4B | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVOL1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROM2 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by mutect2, varscan2
- PSG9 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, varscan2
- PSG9 | c.400del p.E134Kfs*23 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | called by pindel, varscan2
- RBM15 | c.199del p.R67Afs*8 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- RBP3 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- RERGL | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC18A3 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SYCP1 | c.1117C>G p.H373D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.393); called by mutect2, varscan2
- SYCP2 | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 2/9 reads (22%) | called by mutect2, varscan2
- TTLL6 | c.1531del p.D511Tfs*22 (on ENST00000393382 / NM_001130918.3; = p.D204Tfs*22 on NM_173623.3) | Frame Shift Del (DEL) | VAF 48/90 reads (53%) | called by mutect2, pindel, varscan2
- WDR36 | c.2793_2798del p.H931_L932del | In Frame Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- ZNF750 | c.795_796del p.P266* | Frame Shift Del (DEL) | VAF 84/178 reads (47%) | called by pindel, varscan2
- ABCA10 | c.1449C>T p.F483= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99288758; called by muse, mutect2, varscan2
- ABCA13 | c.5661C>T p.V1887= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs560089293, COSV101330087; called by muse, mutect2, varscan2
- ABCB5 | c.2772C>T p.F924= (on ENST00000404938 / NM_001163941.2; = p.F479= on NM_178559.6) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99328622; called by muse, mutect2, varscan2
- ABCB6 | c.342G>A p.E114= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99521944; called by muse, mutect2, varscan2
- ABCB9 | c.1143C>T p.F381= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs550113398, COSV99757727; called by mutect2, varscan2
- AC008397.2 | c.1533C>G p.L511= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99441820; called by muse, mutect2, varscan2
- AC011462.1 | c.72G>A p.Q24= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV60531957, COSV60532381; called by muse, mutect2, varscan2
- ADNP | c.1860G>A p.G620= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs1303943791, COSV100823770; called by muse, varscan2
- AGBL1 | c.2490C>T p.L830= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1490922963, COSV66858887; called by muse, varscan2
- ALK | c.885C>T p.S295= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs1060503882, COSV101202167; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALPK3 | c.192C>T p.F64= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV51928898; called by muse, mutect2, varscan2
- ANAPC10 | c.534C>T p.F178= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV58739094, COSV58740540; called by muse, mutect2, varscan2
- ARID1A | c.3063G>A p.K1021= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100250494; called by muse, varscan2
- ASL | c.732C>T p.F244= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100508911; called by muse, varscan2
- ASL | c.786C>G p.L262= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV59190258; called by muse, varscan2
- ATP1A4 | c.733C>T p.L245= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV63628207; called by muse, mutect2, varscan2
- ATP2B3 | c.1512G>A p.L504= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV54858848; called by muse, mutect2, varscan2
- BCAR3 | c.759C>T p.I253= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99550855; called by muse, mutect2, varscan2
- BLNK | c.351C>T p.G117= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs781863601, COSV99813948; called by muse, mutect2, varscan2
- BMP8B | c.285G>A p.A95= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100863119, COSV65703114; called by muse, mutect2, varscan2
- BMX | c.1596C>T p.F532= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100564500; called by muse, mutect2, varscan2
- C12orf57 | c.380G>A p.*127= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99980775; called by muse, mutect2, varscan2
- C6 | c.1314G>A p.E438= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV54721025; called by muse, mutect2, varscan2
- CACNA1A | c.1653C>T p.F551= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100802622; called by muse, mutect2, varscan2
- CAD | c.5916G>A p.V1972= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53023152, COSV99255201; called by muse, mutect2, varscan2
- CALR3 | c.1125C>T p.F375= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs1411299515, COSV54172572; called by muse, mutect2, varscan2
- CATIP | c.981C>T p.L327= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs758107582, COSV99179556; called by muse, mutect2, varscan2
- CCP110 | c.657C>T p.V219= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101195292; called by muse, mutect2, varscan2
- CEP250 | c.4420C>T p.L1474= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1057169190, COSV100698981; called by muse, mutect2, varscan2
- CEP89 | c.2328G>A p.L776= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV99993553; called by muse, mutect2, varscan2
- CFAP221 | c.1506G>A p.S502= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs371319201, COSV54653891; called by muse, mutect2, varscan2
- CHERP | c.654C>T p.I218= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99550312; called by muse, mutect2, varscan2
- CIDEA | c.366G>A p.K122= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100255130; called by muse, varscan2
- CLIC5 | c.681C>T p.P227= (on ENST00000185206 / NM_001370649.1; = p.P68= on NM_016929.5) | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs151203192; called by muse, mutect2, varscan2
- CLIP4 | c.618C>T p.L206= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs761426811, COSV100191533, COSV100191993; called by muse, mutect2, varscan2
- COL4A6 | c.4902C>T p.I1634= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1384376976, COSV57858576; called by muse, mutect2, varscan2
- COL6A3 | c.4227G>A p.T1409= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs142938239, COSV99798963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.1263C>T p.V421= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as rs763693268, COSV99615909; called by muse, mutect2, varscan2
- CORO1B | c.534C>T p.L178= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100396568; called by muse, mutect2, varscan2
- CYP3A4 | c.822G>A p.L274= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100315570, COSV100315690; called by muse, mutect2, varscan2
- CYP3A4 | c.306C>T p.F102= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100315693; called by muse, mutect2, varscan2
- CYP4F8 | c.699G>A p.V233= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57855824; called by muse, mutect2, varscan2
- DCDC1 | c.1731C>G p.V577= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100663597; called by muse, mutect2, varscan2
- DCTN4 | c.591C>T p.I197= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs138586044, COSV101437560; called by muse, mutect2, varscan2
- DDIAS | c.1989G>A p.Q663= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100231248; called by muse, mutect2, varscan2
- DNAH17 | c.54C>T p.I18= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs368091666, COSV101102580; called by muse, mutect2, varscan2
- DOT1L | c.1776C>T p.L592= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs891622609, COSV101288697, COSV67110891; called by muse, mutect2, varscan2
- DOT1L | c.2227C>T p.L743= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101288698; called by muse, mutect2, varscan2
- DSP | c.4971C>T p.L1657= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV65793514; called by muse, mutect2, varscan2
- ECSIT | c.300C>T p.S100= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs138326885; called by muse, mutect2, varscan2
- EHMT1 | c.2298C>T p.F766= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1289036370, COSV100603966; called by muse, mutect2, varscan2
- EMC3 | c.240C>T p.F80= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV99793974; called by muse, mutect2, varscan2
- ERCC2 | c.1188G>T p.P396= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99676351; called by muse, mutect2, varscan2
- ESRP2 | c.867C>G p.L289= (on ENST00000565858 / NM_001365264.1; = p.L279= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV99251326; called by muse, mutect2, varscan2
- ETHE1 | c.633G>A p.L211= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99415623; called by muse, mutect2, varscan2
- EXTL3 | c.2640C>T p.I880= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV99594076; called by muse, mutect2, varscan2
- FADS2 | c.726C>A p.G242= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs758350373, COSV53899085, COSV99608809; called by muse, mutect2, varscan2
- FAM20B | c.816C>G p.L272= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV99762418; called by muse, mutect2, varscan2
- FAT2 | c.7587C>T p.F2529= | Silent (SNP) | VAF 72/92 reads (78%) | catalogued as COSV55829430, COSV99943209; called by muse, mutect2, varscan2
- FAT2 | c.6234C>T p.I2078= | Silent (SNP) | VAF 59/78 reads (76%) | catalogued as rs1202857083, COSV99943219; called by muse, mutect2, varscan2
- FAT2 | c.5616C>T p.F1872= | Silent (SNP) | VAF 76/98 reads (78%) | catalogued as COSV99943222; called by muse, varscan2
- FAXC | c.519G>A p.V173= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1431945822, COSV101067165; called by muse, mutect2, varscan2
- FBXL18 | c.1659C>T p.I553= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as rs761367418, COSV101154682; called by muse, mutect2, varscan2
- FCGBP | c.7689C>T p.F2563= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs555357841; called by mutect2, varscan2
- FGD4 | c.1821G>A p.L607= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1359299696; called by muse, varscan2
- FKBP3 | c.348G>A p.L116= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs754031720, COSV99361004; called by muse, varscan2
- FOXM1 | c.327C>T p.I109= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100700864, COSV61206863; called by muse, mutect2, varscan2
- FRRS1 | c.1257C>T p.F419= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs752884493, COSV99789981; called by muse, mutect2, varscan2
- FUT1 | c.486G>A p.L162= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV100038151; called by muse, mutect2, varscan2
- GDF15 | c.435C>T p.L145= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99416182, COSV99416247; called by muse, mutect2, varscan2
- GLRB | c.642C>T p.I214= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100029815; called by muse, mutect2, varscan2
- GPAT3 | c.777G>A p.Q259= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100023065; called by muse, mutect2, varscan2
- GPBP1 | c.1341G>A p.K447= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs755000311, COSV99302859; called by muse, mutect2, varscan2
- GPR12 | c.372C>T p.F124= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV101197984; called by muse, mutect2, varscan2
- GPR4 | c.625C>A p.R209= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100547087; called by muse, mutect2, varscan2
- GRIK5 | c.399C>T p.F133= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as rs371423893; called by muse, mutect2, varscan2
- H2AC20 | c.84A>G p.V28= | Silent (SNP) | VAF 60/613 reads (10%) | catalogued as rs782305330, COSV58611520; called by muse, varscan2
- H2AC21 | c.84G>A p.V28= | Silent (SNP) | VAF 58/612 reads (9%) | catalogued as rs931757885, COSV58611616; called by muse, varscan2
- H2BC9 | c.48G>A p.K16= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV99769133; called by muse, mutect2, varscan2
- HAUS2 | c.426C>T p.F142= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1473694637, COSV99535423; called by muse, mutect2, varscan2
- HDLBP | c.870G>A p.E290= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs760725586; called by muse, mutect2, varscan2
- HECW1 | c.906G>A p.S302= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs1483983058, COSV101223828; called by muse, mutect2, varscan2
- HMGCS1 | c.678C>T p.L226= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV100285014; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.63G>A p.L21= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100676508; called by muse, mutect2, varscan2
- HSPA1A | c.51C>T p.C17= | Silent (SNP) | VAF 79/552 reads (14%) | catalogued as rs773049398, COSV65149048; called by muse, varscan2
- HSPA1A | c.66A>G p.Q22= | Silent (SNP) | VAF 77/475 reads (16%) | catalogued as rs930954210, COSV100989409; called by muse, varscan2
- HSPA1L | c.141A>G p.T47= | Silent (SNP) | VAF 104/1055 reads (10%) | catalogued as rs775886586, COSV65148913; called by muse, varscan2
- IFT74 | c.1512G>A p.E504= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV101197187, COSV66288576; called by muse, mutect2, varscan2
- IGDCC4 | c.3432G>A p.G1144= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100732941; called by muse, mutect2, varscan2
- IL27RA | c.831G>C p.L277= | Silent (SNP) | VAF 68/252 reads (27%) | catalogued as COSV54601798, COSV99652213; called by muse, mutect2, varscan2
- INSIG1 | c.51G>A p.A17= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100453000; called by muse, mutect2
- IRX6 | c.1041G>A p.E347= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99306535; called by muse, mutect2, varscan2
- ITM2A | c.486G>A p.L162= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100964459; called by muse, mutect2, varscan2
- JCAD | c.723G>C p.L241= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100948425, COSV64758361; called by muse, mutect2, varscan2
- KCNA7 | c.690C>T p.V230= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99671931; called by muse, mutect2, varscan2
- KCNF1 | c.1155C>T p.L385= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99705751; called by muse, mutect2, varscan2
- KCNG1 | c.1541G>A p.*514= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100857104; called by muse, mutect2, varscan2
- KCNH3 | c.156C>T p.L52= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99235330; called by muse, mutect2, varscan2
- KCNJ10 | c.408C>T p.I136= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV63634610; called by muse, mutect2, varscan2
- KCNMB1 | c.180C>T p.I60= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as rs1275378337, COSV99211168; called by muse, mutect2, varscan2
- KLHDC7B | c.1464C>T p.I488= (on ENST00000395676; = p.I1129= on NM_138433.5) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs766628610, COSV101192952; called by muse, mutect2, varscan2
- KLHL25 | c.1419G>A p.T473= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1474384875, COSV100563620; called by muse, mutect2, varscan2
- KLHL7 | c.645G>A p.L215= (on ENST00000339077 / NM_001031710.3; = p.L167= on NM_018846.5) | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV100178141; called by muse, mutect2, varscan2
- KMT2C | c.11436G>A p.E3812= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100072817, COSV51498734; called by mutect2, varscan2
- KSR1 | c.492C>T p.L164= (on ENST00000644974 / NM_001367810.1; = p.L27= on NM_014238.2) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99259650; called by muse, mutect2, varscan2
- LAMB2 | c.957C>G p.L319= | Silent (SNP) | VAF 90/126 reads (71%) | catalogued as COSV100565285; called by muse, mutect2, varscan2
- LGALS3BP | c.1293C>T p.V431= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99431748; called by muse, mutect2, varscan2
- LVRN | c.2898G>A p.Q966= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1465707201, COSV100773514; called by muse, mutect2, varscan2
- MAPK7 | c.300C>T p.L100= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs376398277; called by muse, mutect2, varscan2
- MAST4 | c.621G>A p.A207= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs1277714381, COSV101282560; called by muse, mutect2, varscan2
- MLLT6 | c.1773C>T p.L591= | Silent (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- MOCS3 | c.741C>G p.V247= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99724300; called by muse, varscan2
- MTIF2 | c.429G>A p.T143= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs753731987, COSV99709153; called by muse, mutect2, varscan2
- NBEA | c.7722G>A p.Q2574= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV100081274; called by muse, mutect2, varscan2
- NCAPG2 | c.1392C>G p.L464= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV51985435; called by muse, mutect2, varscan2
- NEDD9 | c.1596G>A p.V532= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV101060862; called by muse, mutect2, varscan2
- NKIRAS2 | c.108C>T p.I36= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs185243121, COSV100288832; called by muse, mutect2
- NOD1 | c.2463C>A p.G821= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99768182; called by muse, mutect2, varscan2
- NPR1 | c.1452C>T p.L484= | Silent (SNP) | VAF 137/308 reads (44%) | catalogued as rs755193080, COSV100902037; called by muse, mutect2, varscan2
- NT5DC3 | c.531C>T p.L177= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV101230988; called by muse, mutect2, varscan2
- NTRK2 | c.1938G>A p.T646= (on ENST00000323115 / NM_001369534.1; = p.T662= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1481571263, COSV52862772, COSV52884670; called by muse, mutect2, varscan2
- NUAK2 | c.633G>A p.G211= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100904088; called by muse, mutect2, varscan2
- NUGGC | c.657G>A p.A219= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs372445724, COSV58434174; called by muse, mutect2, varscan2
- OGDH | c.2514C>T p.F838= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV99758544, COSV99759033; called by muse, mutect2, varscan2
- OR2V2 | c.534C>T p.F178= | Silent (SNP) | VAF 138/190 reads (73%) | catalogued as rs777738257, COSV100080151; called by muse, mutect2, varscan2
- OR4A15 | c.81C>T p.V27= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs776561607, COSV100124168; called by muse, mutect2, varscan2
- OR4B1 | c.424C>T p.L142= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100535620, COSV58883397; called by muse, mutect2, varscan2
- OR51A4 | c.717C>G p.L239= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs774481902, COSV100985272; called by mutect2, varscan2
- OR8G5 | c.855G>A p.L285= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- P3H4 | c.1074C>T p.L358= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100821258, COSV100821282; called by muse, mutect2, varscan2
- PACS2 | c.2559C>T p.I853= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs377183131; called by muse, mutect2, varscan2
- PARD3B | c.3081G>A p.Q1027= (on ENST00000406610 / NM_001302769.2; = p.Q958= on NM_057177.7) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100593831; called by muse, mutect2, varscan2
- PC | c.579C>T p.F193= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100852256; called by muse, mutect2, varscan2
- PCDH19 | c.1653C>T p.V551= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV55257816; called by muse, mutect2, varscan2
- PDGFA | c.189G>C p.L63= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100627335; called by muse, mutect2, varscan2
- PLB1 | c.1545C>T p.L515= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100215185; called by muse, varscan2
- PLD3 | c.1371G>A p.R457= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as COSV52525572; called by muse, varscan2
- PLD3 | c.1395G>A p.L465= | Silent (SNP) | VAF 70/268 reads (26%) | catalogued as COSV99396759; called by muse, varscan2
- PLEKHG5 | c.288C>G p.L96= (on ENST00000400915 / NM_001042663.3; = p.L59= on NM_020631.6) | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100556897; called by muse, mutect2, varscan2
- PMEL | c.1968C>T p.L656= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV59386022; called by muse, mutect2, varscan2
- PPIL6 | c.270G>A p.V90= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101329661; called by muse, mutect2, varscan2
- PRDM8 | c.750C>A p.A250= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV100325182, COSV60204064; called by muse, mutect2, varscan2
- PTPRF | c.1779C>T p.F593= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs769358679, COSV100740984; called by muse, varscan2
- PXDNL | c.2247C>T p.F749= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs775095055, COSV62484445; called by muse, mutect2
- RASL11B | c.126C>T p.S42= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50535534; called by muse, varscan2
- RNF213 | c.7683G>A p.L2561= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100300782; called by muse, mutect2, varscan2
- RREB1 | c.2758C>T p.L920= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100619436; called by muse, mutect2, varscan2
- RSBN1L | c.93C>G p.L31= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1365563215, COSV100616093; called by muse, mutect2, varscan2
- SAE1 | c.165C>T p.L55= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs776654173, COSV54300080; called by muse, mutect2, varscan2
- SCN10A | c.4941C>T p.F1647= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs1393646938, COSV71862997; called by muse, mutect2, varscan2
- SEC61A2 | c.1101C>T p.F367= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100036469; called by muse, varscan2
- SFXN3 | c.333C>T p.L111= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1045088476, COSV99827504; called by mutect2, varscan2
- SKOR1 | c.1209C>T p.F403= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs770670099, COSV58245181; called by muse, mutect2, varscan2
- SLC35F1 | c.537C>T p.I179= | Silent (SNP) | VAF 55/317 reads (17%) | catalogued as COSV64505342; called by muse, mutect2, varscan2
- SLIT3 | c.3447C>T p.F1149= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1466858037, COSV60596369; called by muse, mutect2, varscan2
- SMG7 | c.546C>T p.V182= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100750371; called by muse, mutect2, varscan2
- SNX15 | c.366C>T p.F122= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100101144, COSV57248691; called by muse, mutect2, varscan2
- SORL1 | c.3510C>T p.C1170= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs762162331, COSV99494225; called by muse, mutect2, varscan2
- SP140 | c.1380C>T p.F460= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100613851; called by muse, mutect2, varscan2
- SRCAP | c.261G>A p.P87= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs375952582; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.600G>A p.T200= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as rs765180618, COSV59129543; called by muse, varscan2
- STK19 | c.978C>G p.L326= (on ENST00000375333 / NM_032454.1; = p.L322= on NM_004197.1) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100941721, COSV100941782; called by muse, mutect2, varscan2
- STX1A | c.339G>A p.L113= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99767502; called by muse, mutect2, varscan2
- STYXL2 | c.687C>T p.I229= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs1348059018, COSV99609389; called by muse, mutect2, varscan2
- SYNE1 | c.6324G>C p.V2108= (on ENST00000367255 / NM_182961.4; = p.V2115= on NM_033071.3) | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99567625; called by muse, mutect2, varscan2
- TACSTD2 | c.864C>T p.L288= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100973752; called by muse, varscan2
- TDRD1 | c.1761G>A p.L587= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99314670; called by muse, mutect2, varscan2
- TENT5A | c.144C>T p.F48= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
- TF | c.1374C>T p.L458= | Silent (SNP) | VAF 71/96 reads (74%) | catalogued as rs1324997366, COSV99395970; called by muse, mutect2, varscan2
- TIMM44 | c.429G>A p.R143= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99564124; called by muse, mutect2, varscan2
- TMEM132B | c.1551C>T p.L517= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs753323504, COSV54754062; called by mutect2, varscan2
- TNFSF10 | c.492G>C p.L164= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV99577769; called by muse, mutect2, varscan2
- TNS4 | c.1539C>T p.I513= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs750186791, COSV99563897; called by muse, mutect2, varscan2
- TRAPPC11 | c.1872C>G p.L624= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100591878; called by muse, mutect2, varscan2
- TTC38 | c.1254C>T p.F418= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs548085409, COSV101123843, COSV101123908; called by muse, mutect2, varscan2
- TTC39C | c.477G>A p.G159= (on ENST00000317571 / NM_001135993.2; = p.G98= on NM_153211.4) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs747781059, COSV100455449; called by mutect2, varscan2
- TTN | c.88635G>A p.V29545= (on ENST00000591111; = p.V22121= on NM_003319.4) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100617417; called by muse, mutect2, varscan2
- VWF | c.1950G>A p.L650= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99779332; called by muse, mutect2, varscan2
- WDFY2 | c.96C>A p.I32= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99987177; called by muse, varscan2
- WDR7 | c.3765G>A p.A1255= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs763260173, COSV99589627; called by muse, mutect2, varscan2
- WFDC9 | c.36C>T p.I12= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100385649; called by muse, mutect2, varscan2
- ZFAND4 | c.867C>T p.P289= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs761725590, COSV100762994, COSV60860570; called by muse, mutect2, varscan2
- ZNF43 | c.771C>G p.L257= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100731841; called by muse, varscan2
- ZNF470 | c.711C>T p.F237= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100401270; called by muse, mutect2, varscan2
- ZNF671 | c.1578G>A p.Q526= | Silent (SNP) | VAF 154/386 reads (40%) | catalogued as COSV100235125; called by muse, varscan2
- ZNF862 | c.705C>T p.F235= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99783553; called by muse, mutect2, varscan2
- ZSCAN10 | c.1146C>T p.C382= (on ENST00000252463; = p.C437= on NM_032805.3) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV52969316, COSV99374295; called by muse, mutect2, varscan2
- AL136982.4 | n.812C>A | RNA (SNP) | VAF 70/330 reads (21%) | called by muse, varscan2
- AL353804.7 | chrX:73845643 G>C | 5'Flank (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- KHDC4 | c.682-223G>C | Intron (SNP) | VAF 3/12 reads (25%) | called by mutect2, varscan2
- KLC4 | c.-26+527G>A | Intron (SNP) | VAF 29/147 reads (20%) | catalogued as COSV99432090; called by muse, varscan2
- MAPT | c.220+2514G>A | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- PLOD1 | c.77-3384C>A | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99538421; called by muse, varscan2
- PRKACA | c.46+3346G>C | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100432086; called by muse, mutect2, varscan2
- RPL13A | c.88+100C>T | Intron (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99201318; called by muse, mutect2, varscan2
- SNORD116-22 | n.71C>T | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2
- ZNF99 | c.*359C>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as COSV101233852; called by muse, mutect2, varscan2
